Gene-level copy-number profile of tumor specimen TCGA-27-1834-01A from TCGA case TCGA-27-1834, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.3 years (20,568 days).
Specimen TCGA-27-1834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.4dcaf772-4b94-4969-8901-7f549da850a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-27-1834-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fde098e9-c13f-4c15-8703-441a7300f933

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 134; copy number 1: 206; copy number 2: 10,662; copy number 3: 20,086; copy number 4: 22,496; copy number 5: 3,189; copy number 6: 3,014; copy number 21: 13; copy number 28: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-27-1834-01A-01D-0591-01): tumor purity 0.74, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,135,598–26,644,595, 77 genes (broad region; genes not listed).
- chr10:50,305,586–57,513,425, 55 genes (within-gene range 0–2): SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD, MBL2, Y_RNA, AC073174.1, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1, PCDH15, RNU6-687P, AL353784.1, NEFMP1, MIR548F1, AC051618.1, AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1, MIR3924, AL731534.1.
- chr11:80,653,429–80,762,826, 2 genes: ARL6IP1P3, LINC02720.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 30 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,218,853–204,377,665, 1 gene, copy number 28 (within-gene range 4–28): PLEKHA6.
- chr1:204,346,776–204,829,274, 16 genes, copy number 28: AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1.
- chr4:53,986,587–54,446,723, 13 genes, copy number 21: RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1.

Autosomal genes at a single copy (total copy number 1): 206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
